Surgical pathology report (de-identified scan), TCGA case TCGA-34-2605, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-2605-01A (Primary Tumor).

[page 1 of 4]
CLINICAL HISTORY

Non-small cell carcinoma.

PREOP DIAGNOSIS: Cancer right upper lobe.

POSTOP DIAGNOSIS: Same.

PROCEDURE: Flexible bronchoscopy/mediastinoscopy, right thoracotomy.

ADDENDUM

Histologic sections of the parts 2 (portion of 6th rib) and part 3 (portion of 5th rib) demonstrate unremarkable bone and bone marrow.

ADDENDUM

Fluorescence in-situ hybridization studies performed on the squamous cell carcinoma shows a ratio of EGFR gene to the centromere of chromosome 7 of 1.02 indicating no EGFR amplification in the targeted region. The rate of hyperploidy for the centromere of chromosome 7 was 48.0% of the analyzed cells. The signal to nucleus ratio (SNR) for the EGFR gene was 2.3.

Interpretation guidelines for EGFR Gene Copy Number by FISH:

Ratio of EGFR to the centromere of chromosome 7:

Less than 2.0: No EGFR amplification

Greater than 2.0: EGFR amplification

Hyperploidy: Greater than two centromere copies/cell.

SNR: The average number of EGFR signals per analyzed cell within the targeted region.

Clinical studies show high EGFR gene copy number by FISH analysis to be associated with favorable clinical benefit (clinical response, stable disease, time to progression, and survival) in patients with advanced non-small cell lung cancer treated with EGFR tyrosine kinase inhibitors.

FINAL DIAGNOSIS**Summary Statement**

The right upper lobe demonstrates two foci of moderately differentiated squamous cell carcinoma (4.5 and 2.7 cm in diameter) associated with visceral pleural and angiolymphatic invasion. Metastatic squamous cell carcinoma is present in one (1) N1 lymph node. Surgical resection margins are free of tumor. Pathologic stage: T4N1Mx.

PART 1: LYMPH NODE, RIGHT LEVEL 4, BIOPSY
FOUR (4) FRAGMENTS OF BENIGN LYMPH NODE.

PARTS 2

AND 3: BONE, PORTION OF 6TH AND 5TH RIBS, RESECTION
PENDING DECALCIFICATION. ADDENDUM REPORT TO FOLLOW.

PART 4: DIAPHRAGM, BIOPSY
HYALINE PLAQUE AND FIBROUS TISSUE WITH CHRONIC INFLAMMATION.

PART 5: LUNG, RIGHT, LOBECTOMY

[page 2 of 4]
- A. INVASIVE SQUAMOUS CELL CARCINOMA (4.5 CM IN DIAMETER) ASSOCIATED WITH GROSSLY IDENTIFIED SATELLITE NODULE OF INVASIVE SQUAMOUS CELL CARCINOMA (2.7 CM IN DIAMETER). VISCERAL PLEURAL AND ANGIOLYMPHATIC INVASION IDENTIFIED. MILD LYMPHOCYTIC HOST RESPONSE. METASTATIC SQUAMOUS CELL CARCINOMA IS PRESENT IN ONE (1) OF TWELVE (12) N1 LYMPH NODES. PATHOLOGIC STAGE: T4N1MX.
- B. SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- C. BACKGROUND LUNG WITH PATCHY ORGANIZING PNEUMONIA AND RESPIRATORY BRONCHOLITIS

COMMENT

{Not Entered}

GROSS DESCRIPTION

The specimen is received in five parts.

Part 1: Specimen is received unfixed identified as "right level 4 lymph node" and with the patient's name, initials

Received are five smooth, rubbery, red-black, anthracotic tissue fragments ranging 0.3 to 1.1 cm in greatest dimension. The tissue is entirely submitted for intraoperative frozen section consultation. The remaining frozen section is entirely submitted labeled AFS.

kas

Part 2 is received fresh labeled with the patient's name and medical record number with the patient's initials

The specimen is designated as "portion of sixth rib". Received is a 1.5 x 0.5 x 0.5 cm fragment of rib. Grossly the rib is unremarkable. A representative section is submitted in cassette 2A after decalcification.

Part 3 is received fresh labeled with the patient's name and medical record number with the patient's initials

The specimen is designated as "portion of fifth rib". Received are three fragments bone, the largest measuring 6.5 x 1.0 x 0.5 cm and the other measures 1.5 x 1.5 x 0.6 cm. The third piece measures 1.8 x 1.5 x 0.5 cm. All three portions of rib are unremarkable. Representative sections of the three fragments are submitted in cassette 3A after decalcification.

Part 4 is received fresh labeled with the patient's name and medical record number with the patient's initials

The specimen is designated as "diaphragmatic biopsy". Received are two fragments of tissue measuring 0.5 x 0.6 x 0.1 cm and a second fragment measuring 0.4 x 0.4 x 0.1 cm. An intraoperative consultation was performed on the specimen and the remainder of the specimen is entirely submitted in cassette 4AFS.

Part 5 is received fresh labeled with the patient's name and medical record number with the patient's initials

The specimen is designated as "right lung". Received is an upper right lung lobe weighing 330 grams and measuring 15.1 x 12.2 x 4.1 cm. The pleural surface is partially stripped on the lateral aspect of the specimen. On sectioning, two lesions are identified. The largest is a 4.5 x 4.0 x 3.5 cm tan-white firm, irregular tumor mass with a central area of necrosis and cavitation measuring 2.5 x 2.5 x 1.5 cm. The tumor is situated near the hilum and grossly involves the main bronchus; however, it does not invade the vascular structures and the bronchial and the vascular margins are grossly free of tumor. The second lesion is a 2.7 x 2.5 x 2.5 cm tan-white irregular tumor tissue situated 1.5 cm distal to the first tumor and grossly reaches the pleural surface causing pleural puckering at the upper pole of the lung lobe. No other lesions are grossly identified. Intraoperative consultations were performed and digital images were obtained. The following sections are submitted:

5AFS frozen section, margins (vascular, bronchial)

5BFS second frozen section (tumor)

5C-5E smaller lesions (in upper pole) (5C/5D are representative sections and 5E is the tumor in closest proximity to the pleural surface)

5F-5I biggest lesion (5F contains the biggest lesion, tumor in closest proximity to the main bronchus, 5G contains the representative section of the biggest tumor, 5H contains the biggest tumor in closest proximity to the pleural surface, 5I contains the representative section of the grossly normal lung tissue between the two lesions)

[page 3 of 4]
5J/5K representative sections of the grossly normal lung tissue away from the two lesions
5L two central lymph nodes
5M five central lymph nodes
5N five peripheral lymph nodes.

MICROSCOPIC DESCRIPTION

SYNOPTIC DATA - PRIMARY LUNG TUMORS
TUMOR LOCATION: Right Upper Lobe
LUNG SEGMENT(S) INVOLVED: Apical, Posterior
PROCEDURE: Lobectomy
TUMOR SIZE: Maximum dimension: 4.5 cm
Minor dimension: 3.5 cm
GROSS SATELLITES: Number of gross satellite lesions: 1
TUMOR TYPE: Invasive squamous carcinoma
HISTOLOGIC GRADE: G2, Moderately differentiated
MICROSCOPIC SATELLITES: Number of microscopic satellite lesions: 0
EXTRAPULMONARY PARENCHYMAL
EXTENSION/INVASION OF TUMOR: Visceral pleura
ANGIOLYMPHATIC INVASION: Yes
TUMOR NECROSIS: > 50%
SURGICAL MARGIN INVOLVEMENT: No
SURGICAL MARGIN SITE: Distance of invasive tumor to closest margin: 5 mm, Bronchial margin
INFLAMMATORY(DESMOPLASTIC) REACTION: Mild
N1 LYMPH NODES: Number of N1 lymph nodes positive:: 1
Number of N1 lymph nodes examined: 12
EXTRACAPSULAR SPREAD OF N1 METASTASES: No
N2 LYMPH NODES: Number of N2 lymph nodes positive: 0
Number of N2 lymph nodes examined: 4
UNDERLYING DISEASE(S): Emphysema, Smokers bronchiolitis, Obstructive pneumonia, focal
T STAGE, PATHOLOGIC: pT4
N STAGE, PATHOLOGIC: pN1
M STAGE, PATHOLOGIC: pMX
ANCILLARY STUDIES: Histochemical stains, FISH studies

Microscopic examination substantiates the above diagnosis. Mucicarmine, PAS and PAS with diastase are negative.

INTRAOPERATIVE DIAGNOSIS

1AFS: LYMPH NODE, RIGHT LEVEL 4, BIOPSY, (frozen section)-

A. BENIGN

B. ANTHRACOTIC PIGMENT IN NODE FRAGMENTS, NEGATIVE FOR NEOPLASM

4AFS: DIAPHRAGMATIC BIOPSY (frozen section)

A. BENIGN.

B. FIBROTIC NODULE WITH VASCULAR PROLIFERATION. NO EVIDENCE OF NEOPLASIA

5AFS: LUNG, RIGHT, BRONCHIAL/VASCULAR MARGIN (frozen section)

A. BENIGN.

[page 4 of 4]
B. NO TUMOR IDENTIFIED.

5BFS: LUNG, RIGHT, TUMOR (frozen section)

A. MALIGNANT.

B. NON-SMALL CELL CARCINOMA

Source: NCI Genomic Data Commons file bad25133-cf67-4290-8d9a-aa7c94e81fb1 (TCGA-34-2605.53291789-2743-4446-B859-AA65568586A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).